Surgical pathology report (de-identified scan), TCGA case TCGA-DV-5569, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site NCI Urologic Oncology Branch, specimen TCGA-DV-5569-01A (Primary Tumor).

[page 1 of 2]
DIAGNOSIS:

1. Kidney, right, "tumor #1" (excision): Renal cyst.
2. Kidney, right, "tumor #2" (excision): Renal cell carcinoma, clear cell type, Furhman nuclear grade 2.
3. Kidney, right, "tumor #3" (excision): Renal cell carcinoma, clear cell type, Furhman nuclear grade 2; chronic interstitial nephritis.

CLINICAL INFORMATION: Brief Clinical History: pt with VHL and right sided kidney tumors

Specimen Taken For [REDACTED] - Yes Allocate Order to Protocol:

[REDACTED]

PROCEDURE: Operative Findings: 3 tumors on right kidney Post-Operative Diagnosis:
VHL Pre-Operative Diagnosis: VHL

SPECIMENS SUBMITTED: 1. KIDNEY, RIGHT, Tumor 1
2. KIDNEY, RIGHT, Tumor 2
3. KIDNEY, RIGHT, Tumor 3

GROSS DESCRIPTION: Received are 3 formalin-filled containers labeled with the patient's name, medical record number, and further specified as follows:

Patient Identification

[REDACTED]

[page 2 of 2]
1. "Right kidney tumor #1". The specimen consists of a red-tan soft tissue fragment measuring 0.5 x 0.3 x 0.2 cm. The specimen is entirely submitted in white cassette labeled [REDACTED] for permanent processing.
2. "Right kidney tumor #2". The specimen consists of a red-tan soft tissue fragment measuring 2.0 x 1.3 x 1.0 cm. The specimen is bisected to reveal a yellow granular cut surface. Approximately 60% is procured for the [REDACTED]. The remaining specimen is sent to Surgical Pathology. In Surgical Pathology, the specimen received matches the above description. The specimen is serially sectioned and entirely submitted in white cassette labeled [REDACTED] for permanent processing.
3. "Right kidney tumor #3". The specimen consists of a red-tan soft tissue mass measuring 2.5 x 2.0 x 1.5 cm. The specimen is bisected to reveal a cystic yellow granular cut surface with focal hemorrhage. Approximately 50% is procured for [REDACTED] and the remaining specimen is sent to Surgical Pathology. In Surgical Pathology, the specimen received matches the above description. The specimen is serially sectioned and entirely submitted in white cassette labeled [REDACTED] for permanent processing.

No consultants

Patient Identification

Source: NCI Genomic Data Commons file 53b3ea6b-5fc7-4f42-a2db-fd6bf45e898f (TCGA-DV-5569.07448BD4-BC42-486D-875C-C606B9FBF8D8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).